Somatic mutation profile of tumor specimen ALCH-AENS-TTP1-A (aliquot ALCH-AENS-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AENS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 46.8 years (17,105 days).
Specimen ALCH-AENS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0354fe75-8d05-4003-88bb-67f89e1db0e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AENS-NB1-A (Blood Derived Normal), aliquot ALCH-AENS-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1533a7c-2baa-4c69-b036-3ac7e5d675c9

The open-access MAF lists 646 somatic variants for this specimen: 429 protein-altering or splice-affecting, 146 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 380, Silent 146, Intron 33, Nonsense Mutation 21, RNA 14, Splice Site 14, 3'UTR 10, 5'UTR 9, Splice Region 7, Frame Shift Del 4, 5'Flank 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4451G>A p.G1484E | Missense Mutation (SNP) | VAF 82/833 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193922405, CM112797; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 57/491 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 62/557 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV100751235; called by muse, mutect2, varscan2
- ADCY10 | c.1839G>A p.M613I | Missense Mutation (SNP) | VAF 50/632 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs748409708; called by muse, mutect2
- ADGRG4 | c.4720C>T p.P1574S | Missense Mutation (SNP) | VAF 42/344 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs752396654; called by muse, mutect2, varscan2
- ADGRV1 | c.7463G>C p.R2488T | Missense Mutation (SNP) | VAF 65/743 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV101316240; called by muse, mutect2
- AL645922.1 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 107/1200 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs772837862, COSV54959324; called by muse, mutect2
- AMER3 | c.713T>A p.V238E | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58465442; called by muse, mutect2, varscan2
- APCS | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 33/530 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs765505336; called by muse, mutect2
- ASNSD1 | c.1646G>A p.R549K | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs764973737; called by muse, varscan2
- ATP10A | c.4196G>T p.G1399V | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV63517696; called by muse, mutect2
- BARX2 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV55652827; called by muse, mutect2
- BNC1 | c.2710G>C p.D904H | Missense Mutation (SNP) | VAF 70/634 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV61757719; called by muse, mutect2, varscan2
- C11orf96 | c.1043C>T p.P348L (on ENST00000339446; = p.P35L on NM_001145033.2) | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs1173353315; called by muse, mutect2
- C20orf194 | c.982-1G>T p.X328_splice | Splice Site (SNP) | VAF 66/591 reads (11%) | catalogued as COSV99330503; called by muse, mutect2, varscan2
- C8orf34 | c.1177C>A p.R393S | Missense Mutation (SNP) | VAF 42/624 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV57398948; called by muse, mutect2
- CBFA2T3 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.037); catalogued as rs1456942734; called by muse, mutect2
- CCDC178 | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV55769806; called by muse, mutect2
- CCT8L2 | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 30/414 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63463005, COSV63463552; called by muse, mutect2
- CENPF | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs1389463240; called by muse, mutect2
- CLSTN2 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 327/1438 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237626169, COSV101515578; called by muse, mutect2, varscan2
- COBL | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 55/542 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1224401011; called by muse, mutect2, varscan2
- CRACD | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 43/440 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.361); catalogued as rs766342310; called by muse, mutect2
- DAPK1 | c.3664G>T p.V1222F | Missense Mutation (SNP) | VAF 30/416 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV104419185, COSV63784695; called by muse, mutect2
- DCAF12L2 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV63582105; called by muse, mutect2, varscan2
- DMXL2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 37/392 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs770888355; called by muse, mutect2
- DNAH11 | c.9015C>A p.C3005* | Nonsense Mutation (SNP) | VAF 42/629 reads (7%) | catalogued as rs771158215; called by muse, mutect2
- DNAH2 | c.7804C>A p.R2602S | Missense Mutation (SNP) | VAF 55/512 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV66729350; called by muse, varscan2
- DNHD1 | c.12478A>G p.M4160V | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as rs1564824811; called by muse, mutect2
- DPP10 | c.1121A>T p.E374V | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as rs773155114; called by muse, mutect2
- EHD2 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs147314520; called by muse, mutect2
- ELAPOR1 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 54/857 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs552107400; called by muse, mutect2
- FAM135B | c.3689G>T p.R1230L | Missense Mutation (SNP) | VAF 217/1045 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52706937, COSV99426607; called by muse, mutect2, varscan2
- FAM174A | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs751002251; called by muse, mutect2, varscan2
- FAM222B | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 60/596 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57929314; called by muse, mutect2
- FAT4 | c.7699C>T p.P2567S | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749170422; called by muse, mutect2, varscan2
- FBF1 | c.136G>T p.G46C (on ENST00000586717; = p.G60C on NM_001319193.1) | Missense Mutation (SNP) | VAF 58/617 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs770139438, COSV59863817; called by muse, mutect2
- FGF23 | c.316C>G p.H106D | Missense Mutation (SNP) | VAF 228/1509 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.461); catalogued as COSV52977391; called by muse, mutect2, varscan2
- FLT4 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 57/608 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs1383801975, COSV56114253; called by muse, mutect2
- GABRA6 | c.1324T>A p.S442T | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs1206640757; called by muse, mutect2
- GAD2 | c.1367G>T p.W456L | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52166606; called by muse, varscan2
- GALNT15 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 80/843 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.294); catalogued as COSV60218606; called by muse, mutect2
- GBA2 | c.1814G>C p.R605P | Missense Mutation (SNP) | VAF 59/560 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100803392, COSV62305803; called by muse, mutect2, varscan2
- GDF3 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 162/1302 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1489168799; called by mutect2, varscan2
- GOLGA8F | c.691G>T p.G231W (on ENST00000526619; = p.G437W on NM_001350920.2) | Missense Mutation (SNP) | VAF 42/1034 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV61897219; called by muse, mutect2
- GPX1 | c.326T>A p.F109Y | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1327162617; called by muse, mutect2, varscan2
- GTF3C1 | c.3265C>G p.R1089G | Missense Mutation (SNP) | VAF 40/463 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.274); catalogued as COSV100649282; called by muse, mutect2
- HAL | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 112/1238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765722855, COSV54117815; called by muse, mutect2
- HOXD8 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as rs936880458, COSV57484817; called by muse, mutect2, varscan2
- HTRA1 | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 124/1796 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750990470, COSV64565047; called by muse, mutect2
- IGKV1D-8 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 78/980 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as rs746722482; called by muse, mutect2
- INCENP | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 85/846 reads (10%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.684); catalogued as COSV53914807; called by muse, mutect2, varscan2
- IQCH | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs112527583; called by muse, mutect2
- ITGA2B | c.2911C>G p.P971A | Missense Mutation (SNP) | VAF 43/526 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.236); catalogued as rs2854737; called by muse, mutect2
- KALRN | c.2728G>C p.E910Q | Missense Mutation (SNP) | VAF 46/746 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1181997211, COSV53766122, COSV99562885; called by muse, mutect2
- KCNA3 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV63901343; called by muse, mutect2, varscan2
- KDM7A | c.2692G>T p.A898S | Missense Mutation (SNP) | VAF 52/700 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.732); catalogued as COSV99134821; called by muse, mutect2
- KIAA1549 | c.3073G>C p.D1025H | Missense Mutation (SNP) | VAF 43/599 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV54318729; called by muse, mutect2
- KIF26B | c.4688G>T p.G1563V | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs774578200; called by muse, mutect2, varscan2
- KLC4 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as COSV52434365; called by muse, mutect2, varscan2
- LAMA2 | c.3589C>A p.L1197M | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV70345428; called by muse, mutect2
- LIN7A | c.622C>A p.R208S | Missense Mutation (SNP) | VAF 78/1114 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV99691803; called by muse, mutect2
- LPA | c.5383G>A p.D1795N | Missense Mutation (SNP) | VAF 58/916 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as rs867143220; called by muse, mutect2
- LPIN3 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 53/668 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs750163513; called by muse, mutect2
- LRRC4C | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 68/818 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.642); catalogued as COSV53430588; called by muse, mutect2
- MAP7D2 | c.1041G>T p.L347F | Missense Mutation (SNP) | VAF 93/621 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as COSV101107351; called by muse, mutect2, varscan2
- MED23 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 64/802 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63430206; called by muse, mutect2
- MERTK | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 90/1026 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV54938209; called by muse, mutect2
- MPRIP | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 64/473 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs778200525, COSV59044709; called by muse, mutect2, varscan2
- MTMR9 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 92/1101 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs766044435; called by muse, mutect2
- MTOR | c.5434G>C p.D1812H | Missense Mutation (SNP) | VAF 82/1138 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV63869558; called by muse, mutect2
- MUC16 | c.24623G>T p.G8208V | Missense Mutation (SNP) | VAF 44/444 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.076); catalogued as COSV67496875; called by muse, mutect2
- MUC16 | c.22897G>C p.E7633Q | Missense Mutation (SNP) | VAF 62/746 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); catalogued as COSV67462851; called by muse, mutect2
- MUC16 | c.16235C>T p.T5412I | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.047); catalogued as COSV67486720; called by muse, mutect2, varscan2
- MYH6 | c.2230A>G p.T744A | Missense Mutation (SNP) | VAF 148/1602 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1366859659, COSV62449098; called by muse, mutect2
- MYO5B | c.2411G>T p.R804L | Missense Mutation (SNP) | VAF 75/1011 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs767203225; called by muse, mutect2
- NBR1 | c.2379C>G p.H793Q | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1433576895; called by muse, mutect2
- NLRP2 | c.399G>A p.A133= | Splice Region (SNP) | VAF 94/984 reads (10%) | catalogued as rs145145515, COSV54759855; called by muse, mutect2
- NLRP5 | c.1273C>A p.R425S | Missense Mutation (SNP) | VAF 54/575 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV66761960, COSV66762753; called by muse, mutect2
- OPRL1 | c.569C>A p.S190* | Nonsense Mutation (SNP) | VAF 24/216 reads (11%) | catalogued as COSV61091232; called by muse, mutect2
- OR10W1 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 51/830 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV67720716; called by muse, mutect2
- OR2M5 | c.161A>T p.Q54L | Missense Mutation (SNP) | VAF 45/556 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); catalogued as COSV100822699; called by muse, mutect2
- OR2T10 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 110/1305 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100393694; called by muse, mutect2
- OR2T3 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs750280326, COSV62082402, COSV62082611; called by muse, mutect2, varscan2
- OR5B21 | c.281G>C p.G94A | Missense Mutation (SNP) | VAF 59/660 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV64482084; called by muse, mutect2
- OR7E24 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 69/944 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.083); catalogued as COSV71702340; called by muse, mutect2
- OR8B8 | c.632C>A p.T211K | Missense Mutation (SNP) | VAF 83/862 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as rs766761696; called by muse, mutect2
- OR8K5 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs992707736, COSV100537259, COSV57891286; called by muse, mutect2
- OS9 | c.1358G>T p.R453L | Missense Mutation (SNP) | VAF 46/526 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.937); catalogued as rs769021605, COSV57782995; called by muse, mutect2
- PARP15 | c.904G>T p.G302C (on ENST00000464300 / NM_001113523.3; = p.G68C on NM_152615.2) | Missense Mutation (SNP) | VAF 37/488 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs547734651, COSV100117305; called by muse, mutect2
- PAX9 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 94/1160 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs375546483, COSV64062118; called by muse, mutect2
- PBX4 | c.1025A>C p.Q342P | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1413853053; called by muse, mutect2, varscan2
- PCDH10 | c.794del p.P265Qfs*5 | Frame Shift Del (DEL) | VAF 75/536 reads (14%) | catalogued as COSV52086680; called by mutect2, pindel, varscan2
- PCDHA12 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 158/1540 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV56498136; called by muse, mutect2, varscan2
- PCDHA4 | c.1940T>A p.L647Q | Missense Mutation (SNP) | VAF 81/750 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63543147; called by muse, mutect2, varscan2
- PDE1C | c.1888G>C p.D630H | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV58513543; called by muse, mutect2, varscan2
- PDZRN4 | c.2719C>G p.R907G (on ENST00000402685 / NM_001164595.2; = p.R649G on NM_013377.4) | Missense Mutation (SNP) | VAF 56/672 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54195827; called by muse, mutect2
- PEG3 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV55634461; called by muse, mutect2
- PLCB1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 24/389 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100570907; called by muse, mutect2
- POLH | c.2012C>A p.P671H | Missense Mutation (SNP) | VAF 45/566 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV64780044; called by muse, mutect2
- POTEC | c.285G>T p.R95S | Missense Mutation (SNP) | VAF 134/1736 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.983); catalogued as rs767315474; called by muse, mutect2
- PTHLH | c.524+8G>T | Splice Region (SNP) | VAF 102/1318 reads (8%) | catalogued as rs370485908; called by muse, mutect2
- PZP | c.4313T>C p.M1438T | Missense Mutation (SNP) | VAF 65/914 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748421651; called by muse, mutect2
- RAPGEF4 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 70/920 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as rs758943183, COSV51381114, COSV99910206; called by muse, mutect2
- RFX7 | c.1073G>A p.S358N (on ENST00000559447 / NM_001368074.1; = p.S455N on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/837 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775011522, COSV57962814; called by muse, mutect2
- RNF180 | c.1763T>G p.F588C | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs958313255; called by muse, mutect2
- ROS1 | c.1387C>A p.Q463K | Missense Mutation (SNP) | VAF 69/614 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs986620798; called by muse, mutect2, varscan2
- RP1 | c.1274G>T p.W425L | Missense Mutation (SNP) | VAF 82/876 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as COSV55113678; called by muse, mutect2
- RYR2 | c.10035G>C p.R3345S | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.351); catalogued as rs754976419; called by muse, mutect2
- SEMA5A | c.2007C>G p.C669W | Missense Mutation (SNP) | VAF 73/794 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as COSV66787008, COSV66803673; called by muse, mutect2
- SERPINA5 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 101/462 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs199628386; called by muse, mutect2, varscan2
- SH3BP4 | c.1150A>C p.N384H | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99060208; called by muse, mutect2
- SHANK1 | c.4283G>T p.S1428I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as rs1344875142; called by muse, mutect2, varscan2
- SLC22A8 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs777689385; called by muse, mutect2
- SLC28A1 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 122/1226 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759169249; called by muse, mutect2
- SMAP2 | c.902C>G p.P301R | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65532285; called by muse, mutect2
- SORBS2 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 46/542 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52998333; called by muse, mutect2
- SPEG | c.5581G>A p.A1861T | Missense Mutation (SNP) | VAF 70/670 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.588); catalogued as rs773969074; called by muse, mutect2
- ST8SIA1 | c.798A>T p.R266S | Missense Mutation (SNP) | VAF 134/798 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV53955111; called by muse, varscan2
- STAB1 | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 54/600 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301920150; called by muse, mutect2
- STARD6 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100323407; called by muse, mutect2
- STON1 | c.1808T>A p.L603Q | Missense Mutation (SNP) | VAF 69/922 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59134920; called by muse, mutect2
- STPG2 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 40/474 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99762080; called by muse, mutect2
- SUSD4 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 57/598 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1202844667, COSV59556355; called by muse, mutect2
- SYNE1 | c.23460+1G>T p.X7820_splice (on ENST00000367255 / NM_182961.4; = p.X7749_splice on NM_033071.3) | Splice Site (SNP) | VAF 36/726 reads (5%) | catalogued as COSV55057122; called by muse, mutect2
- THAP4 | c.1137G>T p.R379S | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as COSV67191241; called by muse, mutect2
- THBS2 | c.291G>T p.R97S | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100827926; called by muse, mutect2
- THEMIS2 | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV100198183; called by muse, mutect2, varscan2
- TLE4 | c.1473C>G p.C491W | Missense Mutation (SNP) | VAF 57/774 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54643717; called by muse, mutect2
- TMEM169 | c.54G>C p.Q18H | Missense Mutation (SNP) | VAF 50/571 reads (9%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV99824443; called by muse, mutect2
- TMEM236 | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 116/1315 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as rs1242908595; called by muse, mutect2
- TMIGD3 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs752898423, COSV62727553; called by muse, mutect2
- TMTC2 | c.1226C>G p.T409R | Missense Mutation (SNP) | VAF 48/442 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs754452313, COSV58263248; called by muse, mutect2, varscan2
- TRAPPC11 | c.3296G>C p.R1099T | Missense Mutation (SNP) | VAF 59/612 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); catalogued as COSV58215916; called by muse, mutect2, varscan2
- TTC19 | c.185-5C>T | Splice Region (SNP) | VAF 13/119 reads (11%) | catalogued as rs1297026837; called by muse, mutect2
- TTN | c.53920C>A p.L17974M (on ENST00000591111; = p.L10550M on NM_003319.4) | Missense Mutation (SNP) | VAF 54/788 reads (7%) | PolyPhen possibly damaging (0.549); catalogued as COSV100621966; called by muse, mutect2
- VCAM1 | c.469C>A p.H157N | Missense Mutation (SNP) | VAF 43/778 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as rs755932839; called by muse, mutect2
- VIT | c.1597C>G p.R533G (on ENST00000389975 / NM_001177969.1; = p.R548G on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/416 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64895682, COSV64896627; called by muse, mutect2
- VWDE | c.2407G>T p.E803* | Nonsense Mutation (SNP) | VAF 48/510 reads (9%) | catalogued as rs143753764, COSV51719670; called by muse, mutect2
- WDR17 | c.905C>A p.T302K | Missense Mutation (SNP) | VAF 40/503 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.146); catalogued as COSV54579484; called by muse, mutect2
- ZDHHC6 | c.226A>T p.M76L | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV65564609; called by muse, mutect2
- ZEB1 | c.1811C>G p.A604G | Missense Mutation (SNP) | VAF 80/924 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as COSV58043420; called by muse, mutect2
- ZMAT1 | c.127A>T p.I43F | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV65657803; called by muse, mutect2, varscan2
- ZNF189 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as rs1359730273; called by muse, mutect2
- ZNF385C | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as COSV56918594; called by muse, mutect2, varscan2
- ZNF536 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 19/309 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV62830724; called by muse, mutect2
- ZNF727 | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1415648999; called by muse, mutect2, varscan2
- ZNF729 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 30/390 reads (8%) | catalogued as rs769322154; called by muse, mutect2
- A2M | c.3673T>A p.S1225T | Missense Mutation (SNP) | VAF 206/1380 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- A2M | c.1006A>T p.T336S | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ABCD2 | c.1510G>T p.G504* | Nonsense Mutation (SNP) | VAF 36/399 reads (9%) | called by muse, mutect2
- ACAP3 | c.2432C>G p.A811G | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2
- ADAM28 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 62/530 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, varscan2
- ADAMTS16 | c.3319C>A p.R1107S | Missense Mutation (SNP) | VAF 64/816 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.145); called by muse, mutect2
- ADAMTS9 | c.4384A>G p.K1462E | Missense Mutation (SNP) | VAF 74/949 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- ADAMTSL2 | c.2417G>A p.C806Y | Missense Mutation (SNP) | VAF 22/355 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADGRB3 | c.794A>T p.Q265L | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2
- ADGRL4 | c.196A>T p.T66S | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); called by muse, mutect2
- ADSS2 | c.1039A>T p.K347* | Nonsense Mutation (SNP) | VAF 40/546 reads (7%) | called by muse, mutect2
- ADSS2 | c.544T>C p.C182R | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.983); called by muse, mutect2
- AFF3 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.005); called by muse, mutect2
- AHCYL2 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.006); called by muse, mutect2
- AK5 | c.1252G>A p.E418K (on ENST00000354567 / NM_174858.3; = p.E392K on NM_012093.4) | Missense Mutation (SNP) | VAF 54/612 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.024); called by muse, mutect2
- AK5 | c.1522G>T p.D508Y (on ENST00000354567 / NM_174858.3; = p.D482Y on NM_012093.4) | Missense Mutation (SNP) | VAF 54/908 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2
- AKAP12 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 39/372 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.034); called by muse, mutect2
- AKR7A3 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ANK1 | c.2652T>G p.Y884* | Nonsense Mutation (SNP) | VAF 56/1568 reads (4%) | called by muse, mutect2
- ARMC4 | c.2377G>T p.V793F | Missense Mutation (SNP) | VAF 93/1034 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2
- ATG13 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 29/497 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2
- ATG7 | c.216-2A>G p.X72_splice | Splice Site (SNP) | VAF 34/320 reads (11%) | called by muse, mutect2, varscan2
- ATP8A1 | c.2846T>A p.L949H | Missense Mutation (SNP) | VAF 23/534 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- ATP8A1 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP8B3 | c.2846-1G>T p.X949_splice | Splice Site (SNP) | VAF 18/277 reads (6%) | called by muse, mutect2
- ATXN2 | c.1269-2A>T p.X423_splice (on ENST00000550104; = p.X263_splice on NM_002973.4) | Splice Site (SNP) | VAF 40/476 reads (8%) | called by muse, mutect2
- AXIN1 | c.2387A>T p.Y796F | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- BMPER | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 92/1148 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.289); called by muse, mutect2
- BRCA1 | c.3497C>A p.A1166D | Missense Mutation (SNP) | VAF 32/714 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.214); called by muse, mutect2
- C10orf53 | c.4C>G p.P2A | Missense Mutation (SNP) | VAF 58/654 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- C10orf53 | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 58/653 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C11orf16 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- C14orf132 | c.279G>C p.W93C (on ENST00000553782 / NM_001289139.2; = p.W62C on NM_001252507.3) | Missense Mutation (SNP) | VAF 153/901 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C6 | c.2763C>A p.N921K | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- CA3 | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1B | c.5635G>C p.G1879R | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.811); called by muse, mutect2
- CACNA1I | c.5269G>T p.G1757C | Missense Mutation (SNP) | VAF 78/572 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- CADM2 | c.695T>A p.I232K (on ENST00000407528 / NM_001167674.2; = p.I234K on NM_153184.4) | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0.005); called by muse, mutect2
- CAMKK1 | c.1319T>A p.L440H | Missense Mutation (SNP) | VAF 54/622 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2
- CAMSAP1 | c.2567G>T p.R856M | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); called by muse, mutect2
- CATSPERE | c.2240G>T p.W747L | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- CC2D1A | c.2075A>T p.E692V | Missense Mutation (SNP) | VAF 62/718 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCSER1 | c.2306A>T p.Y769F | Missense Mutation (SNP) | VAF 80/769 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2
- CDH10 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- CDK11A | c.1091G>T p.R364L (on ENST00000378633 / NM_001313896.2; = p.R361L on NM_024011.4) | Missense Mutation (SNP) | VAF 82/1226 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.502); called by muse, mutect2
- CELA2A | c.323A>T p.H108L | Missense Mutation (SNP) | VAF 82/782 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- CENPE | c.1545A>T p.E515D | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2
- CFAP47 | c.8711G>T p.C2904F | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP61 | c.1528C>G p.Q510E | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2
- CFHR5 | c.1509C>A p.C503* | Nonsense Mutation (SNP) | VAF 41/600 reads (7%) | called by muse, mutect2
- CHERP | c.2539C>A p.Q847K | Missense Mutation (SNP) | VAF 62/555 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CKM | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 45/576 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2
- COL12A1 | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 38/571 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL1A1 | c.154G>C p.V52L | Missense Mutation (SNP) | VAF 116/984 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- COL27A1 | c.2619+1G>T p.X873_splice | Splice Site (SNP) | VAF 56/770 reads (7%) | called by muse, mutect2
- COL3A1 | c.830A>T p.E277V | Missense Mutation (SNP) | VAF 55/756 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); called by muse, mutect2
- COL5A2 | c.4232A>T p.Y1411F | Missense Mutation (SNP) | VAF 76/1012 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- COPS2 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2
- COX4I2 | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 96/701 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPT1A | c.282C>G p.A94= | Splice Region (SNP) | VAF 56/908 reads (6%) | called by muse, mutect2
- CR1 | c.3242A>G p.N1081S | Missense Mutation (SNP) | VAF 148/1802 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); called by muse, mutect2
- CRLS1 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CRTC2 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- CYP2C18 | c.817C>A p.Q273K | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.031); called by muse, mutect2
- CYTH3 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- DDX42 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 56/668 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2
- DMWD | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 44/501 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH9 | c.5710-2A>T p.X1904_splice | Splice Site (SNP) | VAF 26/318 reads (8%) | called by muse, mutect2
- DSG4 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 58/726 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.215); called by muse, mutect2
- DYNLRB2 | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- E2F1 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 42/423 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1574C>A p.S525Y | Missense Mutation (SNP) | VAF 40/940 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.279); called by muse, mutect2
- EHHADH | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 42/696 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ELAVL4 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELMO1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 69/361 reads (19%) | called by muse, mutect2, varscan2
- ELOA2 | c.2019G>T p.K673N | Missense Mutation (SNP) | VAF 58/670 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- EXOC6 | c.1874C>G p.P625R | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); called by muse, mutect2
- FAM110C | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.3); called by mutect2, varscan2
- FAM186A | c.7034+1G>A p.X2345_splice | Splice Site (SNP) | VAF 75/641 reads (12%) | called by muse, mutect2, varscan2
- FAM187A | c.893T>A p.V298E | Missense Mutation (SNP) | VAF 57/716 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAM89A | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- FBN2 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 54/682 reads (8%) | called by muse, mutect2
- FBN3 | c.7174G>C p.A2392P | Missense Mutation (SNP) | VAF 77/722 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FBN3 | c.7173G>T p.Q2391H | Missense Mutation (SNP) | VAF 77/731 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- FBN3 | c.6182G>A p.S2061N | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCGR2A | c.322C>T p.Q108* (on ENST00000271450 / NM_001136219.3; = p.Q107* on NM_021642.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/448 reads (10%) | called by muse, mutect2, varscan2
- FMN2 | c.1517G>C p.G506A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2
- FPR2 | c.997A>G p.N333D | Missense Mutation (SNP) | VAF 38/496 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- FRAS1 | c.688-2A>T p.X230_splice | Splice Site (SNP) | VAF 54/854 reads (6%) | called by muse, mutect2
- GABRA2 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 62/914 reads (7%) | called by muse, mutect2
- GABRA6 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 31/373 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- GALNT17 | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 28/605 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- GALNT2 | c.1137-1G>T p.X379_splice | Splice Site (SNP) | VAF 40/377 reads (11%) | called by muse, mutect2, varscan2
- GALNT9 | c.997C>A p.R333S | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GBX2 | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 23/283 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- GCOM1 | c.453A>T p.Q151H | Missense Mutation (SNP) | VAF 54/938 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2
- GLDN | c.80C>A p.S27* | Nonsense Mutation (SNP) | VAF 37/256 reads (14%) | called by muse, mutect2, varscan2
- GNAI3 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 13/325 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR158 | c.682C>G p.R228G | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- GPX6 | c.541T>A p.W181R | Missense Mutation (SNP) | VAF 56/902 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRB10 | c.1744C>T p.P582S (on ENST00000398812; = p.P536S on NM_001001549.3) | Missense Mutation (SNP) | VAF 89/1096 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIA4 | c.2397C>A p.D799E | Missense Mutation (SNP) | VAF 30/363 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.058); called by muse, mutect2
- GRIN2B | c.4156C>G p.P1386A | Missense Mutation (SNP) | VAF 54/606 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- GRIN2B | c.3147C>A p.Y1049* | Nonsense Mutation (SNP) | VAF 212/1397 reads (15%) | called by muse, mutect2, varscan2
- GRK1 | c.1545del p.I516Sfs*7 | Frame Shift Del (DEL) | VAF 46/518 reads (9%) | called by mutect2, pindel
- HAP1 | c.1049T>G p.L350R | Missense Mutation (SNP) | VAF 61/829 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2
- HCN1 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 32/401 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.116); called by muse, mutect2
- HEPH | c.2590A>T p.I864F (on ENST00000343002; = p.I597F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- HIVEP2 | c.3938T>A p.V1313D | Missense Mutation (SNP) | VAF 60/630 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.013); called by muse, mutect2
- HK1 | c.1951G>C p.V651L | Missense Mutation (SNP) | VAF 108/1170 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2
- HOXD10 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- HS3ST5 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.057); called by muse, mutect2
- HSPB6 | c.170C>G p.A57G | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.429); called by muse, mutect2
- HTT | c.33C>A p.F11L | Missense Mutation (SNP) | VAF 66/796 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2
- HYDIN | c.7314A>T p.Q2438H | Missense Mutation (SNP) | VAF 51/426 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ID2 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 104/861 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IL11RA | c.1245G>T p.R415S | Missense Mutation (SNP) | VAF 99/1337 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2
- IL1B | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 68/824 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IL23R | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 60/744 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- INSYN2B | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- INTS4 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 33/380 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ITGA8 | c.2432C>A p.P811H | Missense Mutation (SNP) | VAF 72/876 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2
- KALRN | c.2407G>T p.D803Y | Missense Mutation (SNP) | VAF 220/1002 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KAT7 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.444); called by muse, mutect2
- KIAA1549L | c.227C>A p.S76* (on ENST00000321505; = p.S373* on NM_012194.3) | Nonsense Mutation (SNP) | VAF 31/340 reads (9%) | called by muse, mutect2
- KIF1C | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 38/484 reads (8%) | called by muse, mutect2
- KIF24 | c.3769A>T p.R1257W | Missense Mutation (SNP) | VAF 66/822 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- KIFC2 | c.1463C>T p.T488I | Missense Mutation (SNP) | VAF 38/512 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- KLHDC7A | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KLHL4 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- KMT2D | c.5808del p.S1937Pfs*110 | Frame Shift Del (DEL) | VAF 22/236 reads (9%) | called by pindel, varscan2*
- KPNA1 | c.1508A>T p.Y503F | Missense Mutation (SNP) | VAF 75/1062 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2
- LRP1B | c.5056A>T p.T1686S | Missense Mutation (SNP) | VAF 34/441 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.73); called by muse, mutect2
- LRP2 | c.3119C>A p.P1040H | Missense Mutation (SNP) | VAF 64/786 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRC55 | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 40/435 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.408); called by muse, mutect2
- MAGOH | c.152A>C p.Y51S | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.348); called by muse, mutect2
- MEGF8 | c.2113A>T p.S705C | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- MOCOS | c.1670T>A p.V557E | Missense Mutation (SNP) | VAF 43/431 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MORC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 71/392 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MPDZ | c.5972A>T p.E1991V (on ENST00000319217 / NM_001330637.2; = p.E1962V on NM_003829.5) | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MS4A6E | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 40/626 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- MYH6 | c.5389C>A p.H1797N | Missense Mutation (SNP) | VAF 102/1150 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.219); called by muse, mutect2
- MYO3A | c.4767G>C p.E1589D | Missense Mutation (SNP) | VAF 38/544 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2
- MYO7A | c.3168G>C p.K1056N | Missense Mutation (SNP) | VAF 19/389 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.07); called by muse, mutect2
- MYO9B | c.5175G>A p.M1725I | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2
- NACAD | c.753G>T p.W251C | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- NLRP11 | c.2306C>A p.A769D | Missense Mutation (SNP) | VAF 29/360 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- NOD2 | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 150/1456 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPDC1 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.395); called by muse, mutect2
- NR3C2 | c.200A>T p.K67I | Missense Mutation (SNP) | VAF 62/887 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- NRIP1 | c.350C>G p.A117G | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- NUP160 | c.3521A>T p.Q1174L | Missense Mutation (SNP) | VAF 36/458 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2
- NUP210L | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.068); called by muse, mutect2
- NUP35 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- NXNL1 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 48/586 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.085); called by muse, mutect2
- NYAP2 | c.1414G>C p.V472L | Missense Mutation (SNP) | VAF 44/548 reads (8%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.99); called by muse, mutect2
- OR10W1 | c.218T>C p.L73P | Missense Mutation (SNP) | VAF 48/834 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- OR1A2 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR1J4 | c.794G>T p.S265I | Missense Mutation (SNP) | VAF 53/654 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); called by muse, mutect2
- OR2A14 | c.794A>G p.H265R | Missense Mutation (SNP) | VAF 81/898 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2
- OR2T2 | c.591G>C p.E197D | Missense Mutation (SNP) | VAF 106/1790 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); called by muse, mutect2
- OR52J3 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 72/1081 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); called by muse, mutect2
- OR5F1 | c.691G>T p.G231W | Missense Mutation (SNP) | VAF 31/403 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR5M10 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ORC3 | c.1655G>A p.R552K | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2
- OTOG | c.1217T>C p.L406S | Missense Mutation (SNP) | VAF 36/447 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH15 | c.4037G>A p.G1346E | Missense Mutation (SNP) | VAF 34/454 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- PCDH15 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 68/932 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA7 | c.2241G>T p.Q747H | Missense Mutation (SNP) | VAF 41/499 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2
- PCDHGA8 | c.1116T>A p.H372Q | Missense Mutation (SNP) | VAF 80/808 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.034); called by muse, mutect2
- PCDHGB6 | c.1295T>C p.L432P | Missense Mutation (SNP) | VAF 45/404 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE3B | c.3295G>T p.A1099S | Missense Mutation (SNP) | VAF 67/622 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PEX6 | c.1234-2A>T p.X412_splice | Splice Site (SNP) | VAF 112/1508 reads (7%) | called by muse, mutect2
- PIEZO1 | c.6342C>A p.F2114L | Missense Mutation (SNP) | VAF 68/341 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PKD1L1 | c.7955T>A p.V2652E | Missense Mutation (SNP) | VAF 69/367 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PLA2G6 | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 66/905 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCB1 | c.3169C>G p.L1057V | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.338); called by muse, mutect2
- PLCH1 | c.1411G>T p.E471* (on ENST00000340059 / NM_001130960.2; = p.E483* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 82/450 reads (18%) | called by muse, mutect2, varscan2
- PLD3 | c.383C>A p.T128N | Missense Mutation (SNP) | VAF 37/320 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PLEKHA4 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 43/428 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLEKHH2 | c.232A>G p.S78G | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- POLR1A | c.1032G>T p.L344F | Missense Mutation (SNP) | VAF 42/411 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- POLR2E | c.231A>T p.P77= | Splice Region (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- POLR3C | c.344A>C p.K115T | Missense Mutation (SNP) | VAF 48/703 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, mutect2
- PPP1R26 | c.323T>A p.M108K | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PPP1R26 | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2
- PREPL | c.242A>G p.E81G | Missense Mutation (SNP) | VAF 50/736 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2
- PRPF40B | c.490C>T p.P164S (on ENST00000380281; = p.P158S on NM_012272.3) | Missense Mutation (SNP) | VAF 74/756 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2
- PRR14L | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 72/903 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSG4 | c.920C>G p.P307R | Missense Mutation (SNP) | VAF 71/833 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); called by muse, mutect2
- PSMA4 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PTGFRN | c.1781G>A p.G594D | Missense Mutation (SNP) | VAF 58/852 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2
- RAB8A | c.582C>G p.D194E | Missense Mutation (SNP) | VAF 84/1053 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- RBM15 | c.2606G>T p.S869I | Missense Mutation (SNP) | VAF 70/684 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- REEP1 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 108/1203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- RPRML | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2
- RYR1 | c.1748A>G p.K583R | Missense Mutation (SNP) | VAF 160/1968 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.809); called by muse, mutect2
- RYR3 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 61/807 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0.069); called by muse, mutect2
- RYR3 | c.5429T>A p.L1810H | Missense Mutation (SNP) | VAF 45/523 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SAG | c.416C>G p.A139G | Missense Mutation (SNP) | VAF 71/1113 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- SCN3A | c.2186G>A p.C729Y | Missense Mutation (SNP) | VAF 60/714 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); called by muse, mutect2
- SDSL | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 76/745 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA4G | c.293C>A p.P98Q | Missense Mutation (SNP) | VAF 38/617 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.933); called by muse, mutect2
- SEPTIN10 | c.846G>T p.W282C | Missense Mutation (SNP) | VAF 62/698 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SERPINB4 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- SKIDA1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, varscan2
- SKOR2 | c.2779C>T p.P927S | Missense Mutation (SNP) | VAF 40/736 reads (5%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2
- SLC13A2 | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 64/564 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by mutect2, varscan2
- SLC22A25 | c.1136T>A p.F379Y | Missense Mutation (SNP) | VAF 52/749 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.501); called by muse, mutect2
- SLC35F5 | c.420T>C p.F140= | Splice Region (SNP) | VAF 30/488 reads (6%) | called by muse, mutect2
- SLC5A8 | c.1136G>T p.R379M | Missense Mutation (SNP) | VAF 32/527 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- SLCO2B1 | c.2102G>C p.G701A | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); called by muse, mutect2
- SLCO3A1 | c.525G>C p.M175I | Missense Mutation (SNP) | VAF 51/586 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.356); called by muse, mutect2
- SMARCAD1 | c.1530G>T p.L510F | Missense Mutation (SNP) | VAF 74/983 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SMC2 | c.2157G>A p.W719* | Nonsense Mutation (SNP) | VAF 30/328 reads (9%) | called by muse, mutect2
- SMR3B | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 34/356 reads (10%) | PolyPhen probably damaging (0.988); called by muse, mutect2
- SORCS1 | c.2870T>A p.V957D | Missense Mutation (SNP) | VAF 46/773 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- SORCS3 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 44/413 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SOS2 | c.1442A>T p.Y481F | Missense Mutation (SNP) | VAF 76/876 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.425); called by muse, mutect2
- SOX10 | c.667dup p.M223Nfs*58 | Frame Shift Ins (INS) | VAF 24/205 reads (12%) | called by mutect2, varscan2
- SPATA17 | c.7A>T p.T3S | Missense Mutation (SNP) | VAF 66/824 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.063); called by muse, mutect2
- SPATA31D5P | n.330T>A | Splice Region (SNP) | VAF 39/393 reads (10%) | called by muse, mutect2
- SPRED3 | c.920G>T p.R307I | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SPRED3 | c.921A>T p.R307S | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SPTBN2 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 49/538 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRP54 | c.1107G>T p.M369I | Missense Mutation (SNP) | VAF 34/411 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.116); called by muse, mutect2
- SSTR1 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 39/534 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- STAB2 | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 60/762 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- STK10 | c.1709G>T p.R570L | Missense Mutation (SNP) | VAF 88/968 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SUPT3H | c.775G>T p.G259W (on ENST00000371460 / NM_181356.3; = p.G248W on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/720 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- SVEP1 | c.6816T>A p.N2272K | Missense Mutation (SNP) | VAF 64/856 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.438); called by muse, mutect2
- SWAP70 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 42/483 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2
- SYCP1 | c.2785C>G p.P929A | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2
- SYNE1 | c.23460G>T p.K7820N (on ENST00000367255 / NM_182961.4; = p.K7749N on NM_033071.3) | Missense Mutation (SNP) | VAF 38/726 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- SYNJ2BP | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- TAAR9 | c.735C>A p.Y245* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | called by mutect2, varscan2
- TAF1 | c.5192A>T p.D1731V (on ENST00000373790 / NM_138923.4; = p.D1752V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- TAX1BP3 | c.8A>T p.Y3F | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM4 | c.4731G>T p.E1577D | Missense Mutation (SNP) | VAF 72/712 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TIAM2 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 90/1106 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.12); called by muse, mutect2
- TLE6 | c.254G>C p.C85S | Missense Mutation (SNP) | VAF 44/562 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.163); called by muse, mutect2
- TMEM270 | c.400T>G p.C134G | Missense Mutation (SNP) | VAF 44/611 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- TNN | c.2143G>C p.V715L | Missense Mutation (SNP) | VAF 146/1372 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- TNRC6C | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.084); called by muse, mutect2
- TOE1 | c.1106A>T p.Q369L | Missense Mutation (SNP) | VAF 61/705 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- TP53BP1 | c.5229C>G p.D1743E | Missense Mutation (SNP) | VAF 97/1191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TRAV36DV7 | c.53-1G>A p.X18_splice | Splice Site (SNP) | VAF 26/188 reads (14%) | called by muse, mutect2, varscan2
- TRBV27 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 41/424 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2
- TRGV2 | c.93G>T p.R31S | Missense Mutation (SNP) | VAF 52/710 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.14); called by muse, mutect2
- TRIP12 | c.4959_4960insT p.E1654* | Frame Shift Ins (INS) | VAF 42/480 reads (9%) | called by mutect2, pindel
- TTN | c.96767G>A p.G32256E (on ENST00000591111; = p.G24832E on NM_003319.4) | Missense Mutation (SNP) | VAF 20/250 reads (8%) | PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.88675G>T p.A29559S (on ENST00000591111; = p.A22135S on NM_003319.4) | Missense Mutation (SNP) | VAF 32/377 reads (8%) | PolyPhen possibly damaging (0.64); called by muse, mutect2
- UBQLN4 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2
- UHRF1BP1L | c.3550G>C p.E1184Q | Missense Mutation (SNP) | VAF 42/644 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2
- UNC80 | c.4182C>G p.I1394M | Missense Mutation (SNP) | VAF 60/916 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- USH2A | c.3016C>G p.L1006V | Missense Mutation (SNP) | VAF 70/744 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.158); called by muse, mutect2
- USP9X | c.3149-7_3149delinsTTTTTTTT p.X1050_splice | Splice Site (ONP) | VAF 6/75 reads (8%) | called by muse*, pindel
- VN1R2 | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 47/464 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- VPS41 | c.1753del p.E585Kfs*69 | Frame Shift Del (DEL) | VAF 53/553 reads (10%) | called by mutect2, pindel, varscan2
- VRK3 | c.1097-1G>T p.X366_splice | Splice Site (SNP) | VAF 32/290 reads (11%) | called by muse, mutect2, varscan2
- VRK3 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2
- VWA5B1 | c.2438T>A p.L813Q | Missense Mutation (SNP) | VAF 52/452 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNK2 | c.5829G>T p.K1943N (on ENST00000297954 / NM_001282394.1; = p.K1906N on NM_006648.3) | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ZBTB2 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 58/588 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- ZC2HC1A | c.76T>G p.F26V | Missense Mutation (SNP) | VAF 35/441 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZCCHC18 | c.364G>C p.G122R | Missense Mutation (SNP) | VAF 69/535 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP28 | c.1772G>T p.C591F | Missense Mutation (SNP) | VAF 44/372 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP57 | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 57/1047 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZFYVE26 | c.6140A>T p.Y2047F | Missense Mutation (SNP) | VAF 124/1539 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- ZNF225 | c.1961G>T p.C654F | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ZNF33A | c.2377G>T p.A793S (on ENST00000458705 / NM_006974.3; = p.A794S on NM_006954.2) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.068); called by muse, mutect2
- ZNF385B | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 46/689 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); called by muse, mutect2
- ZNF432 | c.700G>T p.G234* | Nonsense Mutation (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- ZNF439 | c.1330G>T p.G444W | Missense Mutation (SNP) | VAF 20/341 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF611 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.22); called by muse, mutect2
- ZNF644 | c.1856G>C p.S619T | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.024); called by muse, mutect2
- ZNF726 | c.2167A>T p.T723S | Missense Mutation (SNP) | VAF 25/303 reads (8%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.687); called by muse, mutect2
- ZNF729 | c.3308C>A p.P1103H | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- ZNF736 | c.423T>A p.H141Q | Missense Mutation (SNP) | VAF 30/560 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- ZNF737 | c.1523C>A p.P508H | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.305); called by muse, mutect2
- ZNF90 | c.1220A>G p.K407R | Missense Mutation (SNP) | VAF 30/335 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2
- ABCD4 | c.690G>T p.R230= | Silent (SNP) | VAF 40/498 reads (8%) | called by muse, mutect2
- ABCG5 | c.1558C>T p.L520= | Silent (SNP) | VAF 64/986 reads (6%) | called by muse, mutect2
- AL592490.1 | c.1671G>C p.L557= | Silent (SNP) | VAF 28/344 reads (8%) | catalogued as rs1473964528; called by muse, mutect2
- ANO4 | c.2193C>G p.P731= (on ENST00000392977 / NM_001286615.2; = p.P696= on NM_178826.4) | Silent (SNP) | VAF 31/339 reads (9%) | called by muse, mutect2
- ARHGAP15 | c.579G>A p.K193= | Silent (SNP) | VAF 36/471 reads (8%) | catalogued as rs1229479670; called by muse, mutect2
- ARHGAP28 | c.342A>T p.A114= | Silent (SNP) | VAF 36/313 reads (12%) | called by muse, mutect2, varscan2
- ARID1B | c.4917G>T p.T1639= | Silent (SNP) | VAF 46/726 reads (6%) | catalogued as rs146620657; ClinVar: uncertain significance; called by muse, mutect2
- ARSJ | c.1458C>T p.T486= | Silent (SNP) | VAF 66/722 reads (9%) | called by muse, mutect2
- ATF7IP | c.2409G>C p.G803= | Silent (SNP) | VAF 99/674 reads (15%) | catalogued as rs910341286; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2232C>A p.L744= | Silent (SNP) | VAF 108/1141 reads (9%) | called by muse, mutect2
- BARX2 | c.15C>G p.A5= | Silent (SNP) | VAF 42/443 reads (9%) | called by muse, mutect2
- C6orf118 | c.900A>G p.A300= | Silent (SNP) | VAF 32/480 reads (7%) | called by muse, mutect2
- CADM4 | c.1128C>T p.G376= | Silent (SNP) | VAF 86/962 reads (9%) | catalogued as rs776166752; called by muse, mutect2
- CBLB | c.1830A>G p.L610= | Silent (SNP) | VAF 288/1359 reads (21%) | called by muse, mutect2, varscan2
- CD34 | c.168A>T p.V56= | Silent (SNP) | VAF 32/469 reads (7%) | called by muse, mutect2
- CDH6 | c.186C>T p.L62= | Silent (SNP) | VAF 69/804 reads (9%) | catalogued as rs1362139358; called by muse, mutect2
- CEACAM5 | c.1956C>T p.T652= | Silent (SNP) | VAF 102/1180 reads (9%) | called by muse, mutect2
- CEP290 | c.54G>A p.L18= | Silent (SNP) | VAF 32/452 reads (7%) | catalogued as rs886049885; ClinVar: uncertain significance; called by muse, mutect2
- CFAP74 | c.324G>A p.R108= | Silent (SNP) | VAF 19/194 reads (10%) | catalogued as COSV54564636; called by muse, mutect2
- COL9A2 | c.1458A>T p.P486= | Silent (SNP) | VAF 29/318 reads (9%) | called by muse, mutect2
- CPEB3 | c.1056C>T p.S352= | Silent (SNP) | VAF 36/424 reads (8%) | called by muse, mutect2
- CRB1 | c.3312C>T p.G1104= | Silent (SNP) | VAF 40/796 reads (5%) | called by muse, mutect2
- CSTF3 | c.870C>T p.H290= | Silent (SNP) | VAF 49/600 reads (8%) | called by muse, mutect2
- CWH43 | c.456C>G p.S152= | Silent (SNP) | VAF 24/299 reads (8%) | called by muse, mutect2
- DCC | c.2002A>C p.R668= | Silent (SNP) | VAF 66/694 reads (10%) | called by muse, mutect2
- DDO | c.789C>A p.P263= (on ENST00000368924 / NM_001368172.1; = p.P204= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/190 reads (14%) | catalogued as COSV64470133; called by muse, mutect2, varscan2
- DNAI1 | c.1872T>A p.P624= | Silent (SNP) | VAF 106/1076 reads (10%) | called by muse, mutect2
- DOP1A | c.5535G>A p.R1845= | Silent (SNP) | VAF 44/755 reads (6%) | called by muse, mutect2
- EMILIN2 | c.678A>T p.P226= | Silent (SNP) | VAF 12/233 reads (5%) | called by muse, mutect2
- EPHA6 | c.1164T>A p.S388= | Silent (SNP) | VAF 92/360 reads (26%) | called by muse, varscan2
- EPS15L1 | c.300G>C p.P100= | Silent (SNP) | VAF 62/536 reads (12%) | catalogued as COSV50168511; called by muse, varscan2
- FAM135B | c.4137C>A p.G1379= | Silent (SNP) | VAF 311/1890 reads (16%) | catalogued as COSV99418237; called by muse, mutect2, varscan2
- FAT1 | c.4593G>T p.T1531= | Silent (SNP) | VAF 22/304 reads (7%) | catalogued as COSV101499418; called by muse, mutect2
- FBXL7 | c.1077C>T p.H359= | Silent (SNP) | VAF 42/451 reads (9%) | called by muse, mutect2
- FIGNL1 | c.508C>A p.R170= | Silent (SNP) | VAF 51/542 reads (9%) | catalogued as COSV100794844; called by muse, mutect2
- FLT4 | c.1354C>T p.L452= | Silent (SNP) | VAF 37/438 reads (8%) | called by muse, mutect2
- FOXA2 | c.300G>T p.A100= (on ENST00000377115 / NM_153675.3; = p.A106= on NM_021784.5) | Silent (SNP) | VAF 21/213 reads (10%) | catalogued as COSV101008562; called by muse, mutect2
- FSIP2 | c.5727C>T p.D1909= | Silent (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2
- GABBR1 | c.1917G>A p.L639= | Silent (SNP) | VAF 36/608 reads (6%) | called by muse, mutect2
- GPR32 | c.753C>A p.A251= | Silent (SNP) | VAF 46/452 reads (10%) | called by muse, mutect2, varscan2
- GPR6 | c.547T>C p.L183= | Silent (SNP) | VAF 55/632 reads (9%) | called by muse, mutect2
- GRIN3A | c.627C>A p.L209= | Silent (SNP) | VAF 72/656 reads (11%) | catalogued as COSV62454249; called by muse, mutect2, varscan2
- GRM1 | c.1852C>A p.R618= | Silent (SNP) | VAF 60/1028 reads (6%) | called by muse, mutect2
- GRM1 | c.2331G>C p.V777= | Silent (SNP) | VAF 148/1738 reads (9%) | catalogued as COSV51242213; called by muse, mutect2
- GSTO2 | c.393G>T p.L131= | Silent (SNP) | VAF 54/752 reads (7%) | called by muse, mutect2
- HMG20B | c.780C>T p.T260= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as rs1343656399; called by muse, mutect2
- HSPB6 | c.168C>A p.R56= | Silent (SNP) | VAF 36/462 reads (8%) | called by muse, mutect2
- HYKK | c.192C>A p.L64= | Silent (SNP) | VAF 104/963 reads (11%) | called by muse, mutect2, varscan2
- IGKV3-7 | c.45C>T p.L15= | Silent (SNP) | VAF 98/1112 reads (9%) | catalogued as rs762855875; called by muse, mutect2
- IL1RAPL1 | c.1455G>A p.R485= | Silent (SNP) | VAF 87/514 reads (17%) | catalogued as COSV100145270; called by muse, mutect2, varscan2
- IL36RN | c.390T>G p.P130= | Silent (SNP) | VAF 146/1779 reads (8%) | called by muse, mutect2
- ITPRID1 | c.1710A>G p.V570= | Silent (SNP) | VAF 34/604 reads (6%) | called by muse, mutect2
- IVL | c.843G>T p.G281= | Silent (SNP) | VAF 40/376 reads (11%) | called by muse, mutect2, varscan2
- KCNA4 | c.99T>A p.L33= | Silent (SNP) | VAF 35/315 reads (11%) | called by muse, mutect2, varscan2
- KCNT1 | c.204G>A p.Q68= (on ENST00000488444; = p.Q87= on NM_020822.3) | Silent (SNP) | VAF 60/644 reads (9%) | catalogued as rs777687658; ClinVar: likely benign; called by muse, mutect2
- KIAA0319 | c.738G>A p.E246= | Silent (SNP) | VAF 8/186 reads (4%) | catalogued as COSV65501989; called by muse, mutect2
- KIAA2012 | c.1206C>A p.V402= | Silent (SNP) | VAF 70/792 reads (9%) | called by muse, mutect2
- KLC3 | c.1056G>A p.V352= | Silent (SNP) | VAF 36/387 reads (9%) | called by muse, mutect2
- LAMC2 | c.1932A>G p.V644= | Silent (SNP) | VAF 47/445 reads (11%) | called by muse, mutect2
- LCORL | c.540A>G p.Q180= | Silent (SNP) | VAF 42/480 reads (9%) | called by muse, mutect2
- LHX2 | c.600G>T p.G200= | Silent (SNP) | VAF 15/153 reads (10%) | catalogued as rs764841570; called by muse, mutect2
- LRFN3 | c.300C>G p.A100= | Silent (SNP) | VAF 37/184 reads (20%) | called by muse, mutect2, varscan2
- LRFN4 | c.1881C>G p.A627= | Silent (SNP) | VAF 28/279 reads (10%) | called by muse, mutect2
- LRRK2 | c.3480C>T p.A1160= | Silent (SNP) | VAF 58/870 reads (7%) | catalogued as rs768016253; called by muse, mutect2
- MAB21L1 | c.384C>A p.I128= | Silent (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- MAGEC3 | c.535T>C p.L179= | Silent (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2
- MAP2K1 | c.819G>A p.L273= | Silent (SNP) | VAF 62/684 reads (9%) | called by muse, mutect2
- MCM9 | c.2844A>C p.I948= | Silent (SNP) | VAF 23/284 reads (8%) | called by muse, mutect2
- MED12L | c.5181A>T p.P1727= | Silent (SNP) | VAF 60/723 reads (8%) | called by muse, mutect2
- MEIOC | c.2196T>A p.S732= | Silent (SNP) | VAF 30/436 reads (7%) | called by muse, mutect2
- MMS22L | c.90T>C p.S30= | Silent (SNP) | VAF 60/836 reads (7%) | catalogued as rs1299399728; called by muse, mutect2
- MUC22 | c.822C>T p.G274= | Silent (SNP) | VAF 20/422 reads (5%) | catalogued as rs997480656; called by muse, mutect2
- MUC5AC | c.840C>A p.A280= | Silent (SNP) | VAF 61/601 reads (10%) | called by muse, mutect2, varscan2
- NAV2 | c.2814C>T p.S938= (on ENST00000396087 / NM_001244963.2; = p.S915= on NM_145117.5) | Silent (SNP) | VAF 79/797 reads (10%) | catalogued as rs758261555; called by muse, mutect2, varscan2
- NDC80 | c.243G>A p.K81= | Silent (SNP) | VAF 30/558 reads (5%) | called by muse, mutect2
- NLRP13 | c.1719C>T p.V573= | Silent (SNP) | VAF 40/666 reads (6%) | catalogued as COSV61621926; called by muse, mutect2
- NNMT | c.537G>A p.A179= | Silent (SNP) | VAF 25/318 reads (8%) | catalogued as rs766221246, COSV55474744; called by muse, mutect2
- NPAT | c.237A>T p.P79= | Silent (SNP) | VAF 66/590 reads (11%) | called by muse, mutect2, varscan2
- NPY2R | c.834G>T p.A278= | Silent (SNP) | VAF 33/317 reads (10%) | catalogued as rs550095329, COSV61529085; called by muse, mutect2, varscan2
- NXPE2 | c.18C>A p.L6= | Silent (SNP) | VAF 20/310 reads (6%) | called by muse, mutect2
- OR14A2 | c.252A>T p.L84= | Silent (SNP) | VAF 35/326 reads (11%) | called by muse, mutect2, varscan2
- OR1A1 | c.9A>G p.E3= | Silent (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- OR52E8 | c.468G>C p.L156= | Silent (SNP) | VAF 38/478 reads (8%) | called by muse, mutect2
- OR5T1 | c.480C>A p.S160= | Silent (SNP) | VAF 30/362 reads (8%) | catalogued as COSV57305252; called by muse, mutect2
- OSBPL1A | c.465A>G p.T155= | Silent (SNP) | VAF 36/544 reads (7%) | catalogued as rs748912552; called by muse, mutect2
- OSBPL6 | c.261C>T p.D87= | Silent (SNP) | VAF 48/915 reads (5%) | called by muse, mutect2
- PCDH15 | c.2538C>A p.V846= | Silent (SNP) | VAF 34/544 reads (6%) | catalogued as COSV100218345; called by muse, mutect2
- PCDHB16 | c.1299G>A p.T433= | Silent (SNP) | VAF 96/1022 reads (9%) | catalogued as rs782475588; called by muse, mutect2
- PCDHB3 | c.1452C>A p.A484= | Silent (SNP) | VAF 137/1491 reads (9%) | called by muse, mutect2
- PCDHGA4 | c.573G>T p.P191= | Silent (SNP) | VAF 99/1030 reads (10%) | called by muse, mutect2
- PCDHGA6 | c.1887G>C p.A629= | Silent (SNP) | VAF 50/526 reads (10%) | catalogued as COSV99542535; called by muse, mutect2
- PDHA2 | c.483C>A p.G161= | Silent (SNP) | VAF 70/996 reads (7%) | called by muse, mutect2
- PELI3 | c.780G>A p.S260= | Silent (SNP) | VAF 42/434 reads (10%) | catalogued as rs1397642428; called by muse, mutect2
- PES1 | c.1260C>T p.P420= | Silent (SNP) | VAF 64/770 reads (8%) | catalogued as rs745985162, COSV100073348; called by muse, mutect2
- PIP4P2 | c.534A>G p.K178= | Silent (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- PLCB1 | c.768T>C p.P256= | Silent (SNP) | VAF 24/389 reads (6%) | called by muse, mutect2
- PLEC | c.11343C>A p.R3781= (on ENST00000322810 / NM_201380.4; = p.R3671= on NM_000445.5) | Silent (SNP) | VAF 138/1534 reads (9%) | called by muse, mutect2
- POLR1A | c.2469G>T p.G823= | Silent (SNP) | VAF 59/732 reads (8%) | called by muse, mutect2
- PRR18 | c.474G>A p.A158= | Silent (SNP) | VAF 17/167 reads (10%) | catalogued as rs1419885220; called by muse, mutect2, varscan2
- PRR36 | c.3612G>A p.E1204= | Silent (SNP) | VAF 42/436 reads (10%) | called by muse, mutect2
- RSPH9 | c.135C>T p.L45= | Silent (SNP) | VAF 68/1122 reads (6%) | catalogued as rs765016716; ClinVar: likely benign; called by muse, mutect2
- RTL9 | c.1776A>G p.L592= | Silent (SNP) | VAF 83/507 reads (16%) | called by muse, mutect2, varscan2
- SCN11A | c.1233T>A p.A411= | Silent (SNP) | VAF 100/1158 reads (9%) | called by muse, mutect2
- SCN7A | c.2364A>G p.E788= | Silent (SNP) | VAF 34/422 reads (8%) | called by muse, mutect2
- SF3B1 | c.2910G>A p.L970= | Silent (SNP) | VAF 32/396 reads (8%) | called by muse, mutect2
- SH3RF3 | c.105G>C p.A35= | Silent (SNP) | VAF 13/155 reads (8%) | called by muse, mutect2
- SHC4 | c.264C>G p.P88= | Silent (SNP) | VAF 41/370 reads (11%) | called by muse, mutect2, varscan2
- SLC22A12 | c.688C>A p.R230= | Silent (SNP) | VAF 59/563 reads (10%) | called by muse, mutect2, varscan2
- SORBS1 | c.3528G>T p.R1176= | Silent (SNP) | VAF 44/462 reads (10%) | called by muse, mutect2
- SORCS3 | c.2472C>A p.L824= | Silent (SNP) | VAF 42/412 reads (10%) | called by muse, mutect2, varscan2
- SPACA1 | c.126C>A p.A42= | Silent (SNP) | VAF 40/507 reads (8%) | catalogued as COSV52760913; called by muse, mutect2
- SPAG17 | c.156C>T p.A52= | Silent (SNP) | VAF 32/342 reads (9%) | called by muse, mutect2
- STPG2 | c.642G>T p.P214= | Silent (SNP) | VAF 40/468 reads (9%) | called by muse, mutect2
- STXBP3 | c.954A>G p.T318= | Silent (SNP) | VAF 38/386 reads (10%) | called by muse, mutect2
- STXBP4 | c.444C>A p.I148= | Silent (SNP) | VAF 36/550 reads (7%) | called by muse, mutect2
- SYTL5 | c.771C>A p.T257= | Silent (SNP) | VAF 53/313 reads (17%) | catalogued as COSV52898339; called by muse, mutect2, varscan2
- TAAR8 | c.318T>A p.L106= | Silent (SNP) | VAF 46/632 reads (7%) | catalogued as COSV51586175; called by muse, mutect2
- TACR1 | c.486C>T p.A162= | Silent (SNP) | VAF 42/610 reads (7%) | catalogued as rs1304229153; called by muse, mutect2
- TATDN3 | c.252A>G p.T84= | Silent (SNP) | VAF 36/406 reads (9%) | catalogued as rs1428591649; called by muse, mutect2
- TDRD10 | c.117C>T p.G39= | Silent (SNP) | VAF 33/430 reads (8%) | called by muse, mutect2
- TEC | c.1689A>G p.R563= | Silent (SNP) | VAF 16/225 reads (7%) | called by muse, mutect2
- TLR9 | c.1971G>A p.V657= | Silent (SNP) | VAF 58/491 reads (12%) | called by muse, mutect2, varscan2
- TRIM42 | c.90C>A p.I30= | Silent (SNP) | VAF 314/1133 reads (28%) | called by muse, mutect2, varscan2
- TRPV3 | c.1551C>T p.L517= | Silent (SNP) | VAF 43/454 reads (9%) | called by muse, mutect2
- TTN | c.102294C>T p.N34098= (on ENST00000591111; = p.N26674= on NM_003319.4) | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- TTN | c.87162T>C p.S29054= (on ENST00000591111; = p.S21630= on NM_003319.4) | Silent (SNP) | VAF 23/214 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.69939C>A p.L23313= (on ENST00000591111; = p.L15889= on NM_003319.4) | Silent (SNP) | VAF 36/397 reads (9%) | called by muse, mutect2
- TTN | c.54312C>A p.T18104= (on ENST00000591111; = p.T10680= on NM_003319.4) | Silent (SNP) | VAF 68/900 reads (8%) | catalogued as COSV60359482; called by muse, mutect2
- TTN | c.5628C>G p.L1876= (on ENST00000591111; = p.L1830= on NM_003319.4) | Silent (SNP) | VAF 76/1155 reads (7%) | called by muse, mutect2
- TTN | c.3477C>T p.R1159= (on ENST00000591111; = p.R1113= on NM_003319.4) | Silent (SNP) | VAF 74/922 reads (8%) | called by muse, mutect2
- UEVLD | c.810G>T p.V270= | Silent (SNP) | VAF 60/878 reads (7%) | called by muse, mutect2
- UNC45B | c.1608C>G p.A536= | Silent (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- USP31 | c.3202C>T p.L1068= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as COSV54855477; called by muse, mutect2
- VPS13D | c.8652G>C p.R2884= | Silent (SNP) | VAF 49/500 reads (10%) | called by muse, mutect2
- VSTM2L | c.201C>T p.S67= | Silent (SNP) | VAF 44/549 reads (8%) | catalogued as rs773073130; called by muse, mutect2
- WBP11 | c.1185G>A p.Q395= | Silent (SNP) | VAF 208/1613 reads (13%) | catalogued as rs1274813867; called by muse, mutect2, varscan2
- WBP11 | c.852C>T p.D284= | Silent (SNP) | VAF 66/497 reads (13%) | catalogued as rs757281739, COSV53762603; called by muse, mutect2, varscan2
- XCR1 | c.951G>C p.S317= | Silent (SNP) | VAF 40/380 reads (11%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.360G>A p.Q120= | Silent (SNP) | VAF 70/525 reads (13%) | catalogued as COSV64367833; called by muse, mutect2, varscan2
- XYLT1 | c.48G>T p.S16= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- ZBTB40 | c.1335A>G p.K445= | Silent (SNP) | VAF 36/451 reads (8%) | called by muse, mutect2
- ZIC2 | c.1275C>A p.S425= | Silent (SNP) | VAF 48/388 reads (12%) | catalogued as COSV66254692; called by muse, varscan2
- ZNF479 | c.195C>A p.I65= | Silent (SNP) | VAF 27/369 reads (7%) | catalogued as rs572625870, COSV58641721, COSV58642077; called by muse, mutect2
- ZNF479 | c.21C>T p.P7= | Silent (SNP) | VAF 138/1033 reads (13%) | catalogued as COSV58637571; called by muse, varscan2
- ZNF529 | c.1584T>C p.H528= | Silent (SNP) | VAF 57/506 reads (11%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.1083G>T p.A361= | Silent (SNP) | VAF 60/529 reads (11%) | called by muse, mutect2, varscan2
- AC004951.2 | n.351A>G | RNA (SNP) | VAF 100/1666 reads (6%) | catalogued as rs17151757; called by muse, mutect2
- AC064807.1 | n.1102G>T | RNA (SNP) | VAF 32/302 reads (11%) | called by muse, mutect2, varscan2
- AC114490.3 | c.*577G>T | 3'UTR (SNP) | VAF 33/272 reads (12%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9100C>A | Intron (SNP) | VAF 110/1232 reads (9%) | catalogued as rs782803380; called by muse, mutect2
- ADAMTSL1 | c.5182+44G>C | Intron (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2
- AF241726.1 | c.172-444693del | Intron (DEL) | VAF 46/305 reads (15%) | called by mutect2, pindel, varscan2
- AL353804.4 | chrX:73821603 G>T | 3'Flank (SNP) | VAF 62/409 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.544-184A>T | Intron (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- ASIC1 | c.559-3466G>A | Intron (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- ATP6V1G2 | c.*685A>G | 3'UTR (SNP) | VAF 52/636 reads (8%) | catalogued as rs1338601573; called by muse, mutect2
- BTBD7 | c.-188G>T | 5'UTR (SNP) | VAF 75/333 reads (23%) | called by muse, mutect2, varscan2
- CACNA1C | c.1391-2447T>C | Intron (SNP) | VAF 113/891 reads (13%) | catalogued as COSV100219244; called by muse, mutect2, varscan2
- CACNA1C | c.3913-6755C>T | Intron (SNP) | VAF 54/569 reads (9%) | called by muse, mutect2
- CEACAM4 | c.-6G>C | 5'UTR (SNP) | VAF 13/182 reads (7%) | called by muse, mutect2
- CHN1 | c.*439A>G | 3'UTR (SNP) | VAF 120/1186 reads (10%) | called by muse, mutect2
- CLK2P1 | n.768T>G | RNA (SNP) | VAF 149/1596 reads (9%) | called by muse, mutect2
- CNKSR2 | c.228+53G>A | Intron (SNP) | VAF 23/127 reads (18%) | catalogued as COSV99668906; called by muse, mutect2, varscan2
- CSMD2 | c.8138-10C>T | Intron (SNP) | VAF 94/960 reads (10%) | called by muse, mutect2
- CYTH2 | c.808+1114G>C | Intron (SNP) | VAF 12/250 reads (5%) | called by muse, mutect2
- DPEP1 | c.-1C>T | 5'UTR (SNP) | VAF 48/484 reads (10%) | catalogued as rs748498388; called by muse, mutect2, varscan2
- DPY19L2 | c.1053+1242T>C | Intron (SNP) | VAF 50/546 reads (9%) | called by muse, mutect2
- DZIP1L | c.2142+138C>T | Intron (SNP) | VAF 34/431 reads (8%) | catalogued as rs1267956566; called by muse, mutect2
- EIF2B5 | c.789+623C>A | Intron (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
- FAM184A | c.1653+25C>A | Intron (SNP) | VAF 37/361 reads (10%) | called by muse, mutect2, varscan2
- FANCL | chr2:58241345 C>G | 5'Flank (SNP) | VAF 86/980 reads (9%) | catalogued as COSV99287537; called by muse, mutect2
- FGD4 | c.-97A>G | 5'UTR (SNP) | VAF 30/328 reads (9%) | called by muse, mutect2
- GCSAML | c.-56-10454G>A | Intron (SNP) | VAF 34/320 reads (11%) | called by muse, mutect2, varscan2
- GUSBP4 | n.56G>T | RNA (SNP) | VAF 37/882 reads (4%) | called by muse, mutect2
- HERC6 | c.200-26G>T | Intron (SNP) | VAF 53/585 reads (9%) | called by muse, mutect2
- HIF3A | c.770+1235C>A | Intron (SNP) | VAF 42/407 reads (10%) | called by muse, mutect2, varscan2
- HSP90B3P | n.590T>C | RNA (SNP) | VAF 58/690 reads (8%) | catalogued as rs755049898; called by muse, mutect2
- INPP1 | c.-65+173C>T | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- KIAA2012 | c.369+1809G>A | Intron (SNP) | VAF 60/645 reads (9%) | called by muse, mutect2
- LHX1 | c.675+167C>A | Intron (SNP) | VAF 100/1192 reads (8%) | called by muse, mutect2
- LINC00602 | n.1179C>T | RNA (SNP) | VAF 31/253 reads (12%) | called by muse, mutect2, varscan2
- LINC01559 | n.519G>C | RNA (SNP) | VAF 71/1070 reads (7%) | called by muse, mutect2
- LSS | c.-40T>C | 5'UTR (SNP) | VAF 26/239 reads (11%) | called by muse, mutect2, varscan2
- MGAM | c.4619-10039C>T | Intron (SNP) | VAF 44/578 reads (8%) | called by muse, mutect2
- MGAT4C | c.-61G>T | 5'UTR (SNP) | VAF 32/508 reads (6%) | catalogued as COSV59829811; called by muse, mutect2
- MIR329-2 | n.25G>A | RNA (SNP) | VAF 47/333 reads (14%) | catalogued as rs1299172342; called by muse, mutect2, varscan2
- MIR596 | n.24C>G | RNA (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- MSLN | c.1807+15C>A | Intron (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- MSLNL | c.504-11G>A | Intron (SNP) | VAF 21/264 reads (8%) | called by muse, mutect2
- MUC19 | n.5424C>A | RNA (SNP) | VAF 42/758 reads (6%) | called by muse, mutect2
- NF1 | chr17:31378881 C>A | 3'Flank (SNP) | VAF 76/888 reads (9%) | called by muse, mutect2
- NPIPB1P | n.500G>A | RNA (SNP) | VAF 78/1156 reads (7%) | catalogued as rs748985234; called by muse, mutect2
- NPIPB1P | n.222A>G | RNA (SNP) | VAF 42/502 reads (8%) | called by muse, mutect2
- OR2L1P | n.607A>T | RNA (SNP) | VAF 36/474 reads (8%) | called by muse, mutect2
- OR7E5P | n.375G>C | RNA (SNP) | VAF 64/915 reads (7%) | called by muse, mutect2
- PAX8 | c.-54G>T | 5'UTR (SNP) | VAF 19/353 reads (5%) | catalogued as rs995093943; called by muse, mutect2
- PCYT1B | c.*170G>T | 3'UTR (SNP) | VAF 54/341 reads (16%) | catalogued as rs758919272, COSV100770810; called by muse, mutect2, varscan2
- PKHD1L1 | c.-1A>C | 5'UTR (SNP) | VAF 58/599 reads (10%) | called by muse, mutect2, varscan2
- RNF224 | c.-70A>T | 5'UTR (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- RNU7-174P | chr8:80558914 C>A | 5'Flank (SNP) | VAF 71/1013 reads (7%) | called by muse, mutect2
- SEC61A1 | c.7+31C>G | Intron (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- SLC5A1 | chr22:32039568 A>T | 5'Flank (SNP) | VAF 242/1644 reads (15%) | called by muse, mutect2, varscan2
- SMARCA4 | c.3775-38G>T | Intron (SNP) | VAF 68/722 reads (9%) | called by muse, mutect2
- SPG7 | c.*8G>T | 3'UTR (SNP) | VAF 51/297 reads (17%) | catalogued as rs1321724191; called by muse, mutect2, varscan2
- SPINK4 | c.*23A>G | 3'UTR (SNP) | VAF 78/680 reads (11%) | called by muse, mutect2, varscan2
- STK32C | c.319-29G>T | Intron (SNP) | VAF 76/719 reads (11%) | called by muse, mutect2, varscan2
- STPG1 | c.*149G>T | 3'UTR (SNP) | VAF 110/1119 reads (10%) | called by muse, mutect2
- STPG1 | c.*17C>G | 3'UTR (SNP) | VAF 65/881 reads (7%) | called by muse, mutect2
- TBX1 | c.1009+30C>T | Intron (SNP) | VAF 24/177 reads (14%) | catalogued as rs1342979923; called by muse, mutect2, varscan2
- TEDC2 | c.125+23G>T | Intron (SNP) | VAF 16/468 reads (3%) | called by muse, mutect2
- TEX36-AS1 | n.514+408G>C | Intron (SNP) | VAF 24/449 reads (5%) | called by muse, mutect2
- TPM1 | c.115-39C>T | Intron (SNP) | VAF 47/445 reads (11%) | called by muse, mutect2, varscan2
- TPO | c.2387-131dup | Intron (INS) | VAF 47/523 reads (9%) | called by mutect2, pindel
- XIRP2 | c.*1357T>A | 3'UTR (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- Z96074.1 | n.151+3023G>A | Intron (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- ZNF574 | c.*9G>T | 3'UTR (SNP) | VAF 61/758 reads (8%) | catalogued as COSV99725868; called by muse, mutect2
- ZNF772 | c.72+88G>C | Intron (SNP) | VAF 36/394 reads (9%) | called by muse, mutect2
